Somatic mutation profile of tumor specimen MMRF_2471_1_BM_CD138pos (aliquot MMRF_2471_1_BM_CD138pos_T1_KHS5U_L11597) from MMRF case MMRF_2471, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,170 days).
Specimen MMRF_2471_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c1b549-d7f2-4bb7-9146-a9ffab14ef80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2471_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2471_1_PB_CD3pos_C3_KHS5U_L11598; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d2a4e28-12df-4e27-ba18-d8e7f0f53a70

The open-access MAF lists 70 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 19, Silent 10, Intron 6, Nonsense Mutation 3, 5'UTR 2, Splice Site 2, 5'Flank 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGDIB | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs758839655; called by muse, mutect2, varscan2
- DYRK2 | c.1403C>T p.T468M (on ENST00000344096 / NM_006482.3; = p.T395M on NM_003583.4) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs1232806533; called by muse, mutect2, varscan2
- IGHV2-70 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.37); catalogued as rs192620545; called by muse, varscan2
- IGHV2-70 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376985995; called by muse, varscan2
- IGHV2-70 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375225384; called by muse, varscan2
- IGHV2-70 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs546262332; called by muse, mutect2, varscan2
- OR2F2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs755050627; called by muse, varscan2
- OR6B1 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68770610, COSV68770671; called by muse, mutect2
- PARD3 | c.3596T>C p.V1199A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100632190; called by muse, mutect2, varscan2
- PDE2A | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1193120816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKP | c.1090-1G>C p.X364_splice | Splice Site (SNP) | VAF 22/158 reads (14%) | catalogued as COSV66899381; called by muse, mutect2, varscan2
- RIMBP2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs146381205; called by muse, mutect2, varscan2
- SHROOM3 | c.3541G>A p.G1181R | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs770088687, COSV99934719; called by muse, mutect2, varscan2
- SP140 | c.1946G>A p.W649* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV59446021; called by muse, mutect2, varscan2
- YTHDF1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV64834279; called by muse, mutect2
- DSG2 | c.1768G>T p.V590F | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DUOX2 | c.2669T>C p.I890T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- EARS2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR6 | c.728A>C p.H243P | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- IGHV2-5 | c.46+2T>C p.X16_splice | Splice Site (SNP) | VAF 74/76 reads (97%) | called by muse, mutect2, varscan2
- ITGA9 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 71/184 reads (39%) | called by muse, mutect2, varscan2
- ITPK1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- SLC30A3 | c.149T>A p.M50K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZCCHC4 | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 138/305 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CCDC85A | c.783A>G p.K261= | Silent (SNP) | VAF 117/248 reads (47%) | catalogued as COSV68153884; called by muse, mutect2, varscan2
- H2BC12 | c.307C>T p.L103= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs755710813; called by muse, mutect2, varscan2
- IFITM2 | c.216G>A p.L72= | Silent (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- KCNC3 | c.255C>T p.G85= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1319314099; called by muse, mutect2, varscan2
- PRR30 | c.732C>G p.A244= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- PTK6 | c.102C>T p.V34= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- SORCS1 | c.181C>A p.R61= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1368355330; called by muse, varscan2
- SVEP1 | c.7197T>C p.H2399= | Silent (SNP) | VAF 48/217 reads (22%) | called by muse, varscan2
- YTHDF1 | c.645C>A p.V215= | Silent (SNP) | VAF 30/674 reads (4%) | called by muse, mutect2
- ZNF879 | c.975C>T p.F325= | Silent (SNP) | VAF 74/173 reads (43%) | called by muse, mutect2, varscan2
- ABHD6 | c.119+1857C>T | Intron (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.*11C>G | 3'UTR (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- ARF1 | c.*1172A>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- BEND4 | c.*1499C>A | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- BIRC3 | c.*787A>G | 3'UTR (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- BTNL9 | c.737-62G>T | Intron (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- CAND1 | c.*388A>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- CIDEC | c.*130C>A | 3'UTR (SNP) | VAF 84/182 reads (46%) | catalogued as rs897082581; called by muse, mutect2, varscan2
- COPS9 | c.*56C>G | 3'UTR (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- DOCK7 | c.5508+183G>A | Intron (SNP) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- ELL2 | c.*3124dup | 3'UTR (INS) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- ENPP2 | c.-5G>A | 5'UTR (SNP) | VAF 32/64 reads (50%) | called by mutect2, varscan2
- GALNT13 | c.*3145T>A | 3'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- GLRA3 | c.*3250C>G | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- GRINA | c.*220A>G | 3'UTR (SNP) | VAF 81/169 reads (48%) | catalogued as rs868912887; called by muse, mutect2, varscan2
- HNRNPD | c.460-10A>G | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- HTR2C | c.*1866A>C | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- KLHL14 | chr18:32773990 G>T | 5'Flank (SNP) | VAF 24/56 reads (43%) | catalogued as rs977320030; called by muse, mutect2, varscan2
- KRTAP19-1 | c.*127T>C | 3'UTR (SNP) | VAF 80/233 reads (34%) | called by muse, mutect2, varscan2
- MIR5195 | n.3G>A | RNA (SNP) | VAF 68/130 reads (52%) | catalogued as rs535424470; called by muse, varscan2
- MIR5195 | chr14:106851180 C>G | 5'Flank (SNP) | VAF 94/185 reads (51%) | catalogued as rs551757315; called by muse, varscan2
- NKX6-3 | c.*247C>G | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- PFAS | c.2822-66C>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- PHF21B | c.*300C>G | 3'UTR (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- PIM1 | c.*440A>C | 3'UTR (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- PMM2 | chr16:8849347 C>G | 3'Flank (SNP) | VAF 45/82 reads (55%) | catalogued as rs1310189532; called by muse, varscan2
- POU3F3 | c.*92_*103dup | 3'UTR (INS) | VAF 4/8 reads (50%) | catalogued as rs895839135; called by muse*, mutect2
- PRKCB | c.-145G>A | 5'UTR (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- PRSS23 | c.*867G>A | 3'UTR (SNP) | VAF 48/147 reads (33%) | catalogued as COSV99722538; called by muse, mutect2, varscan2
- PRTG | c.*607T>A | 3'UTR (SNP) | VAF 48/130 reads (37%) | catalogued as rs953009777; called by muse, mutect2
- PXYLP1 | c.*896A>G | 3'UTR (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- RNF44 | c.1237-61C>A | Intron (SNP) | VAF 189/266 reads (71%) | called by muse, mutect2, varscan2
- SLC10A2 | c.*1352G>C | 3'UTR (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- SNTN | c.*1040G>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SSR2 | c.*259G>A | 3'UTR (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- WNT2B | c.*3836G>A | 3'UTR (SNP) | VAF 48/91 reads (53%) | catalogued as rs1474013507; called by muse, mutect2, varscan2
